Somatic mutation profile of tumor specimen TCGA-V1-A9OX-01A (aliquot TCGA-V1-A9OX-01A-11D-A41K-08) from TCGA case TCGA-V1-A9OX, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9OX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48742a6b-a9d7-469c-af07-d054e7a8562f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9OX-10A (Blood Derived Normal), aliquot TCGA-V1-A9OX-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d99f7167-c118-4b66-84c9-20d01d1f39d0

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, Intron 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1M2 | c.608T>G p.F203C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV99140740; called by muse, mutect2, varscan2
- BTG4 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV100604373; called by muse, mutect2, varscan2
- CCT2 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1040690949, COSV100167522; called by muse, mutect2, varscan2
- CPS1 | c.3490G>A p.V1164M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242328; called by muse, mutect2, varscan2
- ELAPOR1 | c.2696T>G p.V899G | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV100884410; called by muse, mutect2, varscan2
- GAK | c.1857G>A p.R619= | Splice Region (SNP) | VAF 12/50 reads (24%) | catalogued as rs1391761606, COSV100033228; called by muse, mutect2, varscan2
- INTS11 | c.601A>T p.I201F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100028046; called by muse, mutect2, varscan2
- KMT2C | c.8273C>T p.A2758V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100068073, COSV51517469; called by muse, mutect2
- MYO1H | c.2183G>C p.R728T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.506); catalogued as COSV100183159; called by muse, mutect2, varscan2
- TBX18 | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100858447; called by muse, mutect2, varscan2
- TRIM5 | c.1027A>T p.N343Y | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV59900578; called by muse, mutect2, varscan2
- ZNF365 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1232726531, COSV67925477; called by muse, mutect2, varscan2
- TMPRSS2 | c.909_911del p.N304del | In Frame Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- A2M | c.3282A>C p.G1094= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100588488; called by muse, mutect2
- GRN | c.828G>A p.A276= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs761530797, COSV50006406; called by muse, mutect2, varscan2
- HCFC1 | c.5655G>A p.T1885= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as rs781951219, COSV60076717; called by muse, mutect2, varscan2
- OR4C11 | c.834C>A p.P278= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV56353452; called by muse, mutect2, varscan2
- PCDHB6 | c.1059C>T p.L353= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV50693806; called by muse, mutect2, varscan2
- SMAD9 | c.282C>T p.R94= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs779255458, COSV63204899; called by muse, mutect2, varscan2
- SV2A | c.351G>A p.A117= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs200889129, COSV100975030; called by muse, mutect2, varscan2
- TSHZ3 | c.2304C>T p.P768= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs763832150, COSV99550796; called by muse, mutect2, varscan2
- CASR | c.1378-6236G>A | Intron (SNP) | VAF 21/89 reads (24%) | catalogued as rs1382392248, COSV99948529; called by muse, mutect2, varscan2
